Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3C1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3C1-06A (Metastatic).

DIAGNOSIS

Patient ID –

(A) LEFT AXILLA, LYMPH NODES:

METASTATIC MELANOMA IN FOUR OF FORTY TWO LYMPH NODES (4/42)

LARGEST SIZE IS 24.0 MM

SUBCAPSULAR AND INTRAPARENCHYMAL, WITH FOCAL EXTRANODAL EXTENSION.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RE-EXCISION MELANOMA, LEFT AXILLA - An en block resection of axillary contents with an attached ellipse of skin that measures overall 19.0 x 10.5 x 3.0 cm. The attached unoriented portion of skin is 4.5 x 1.6 cm. A centrally located possible scar measuring 3.5 x 0.8 cm is present. No biopsy cavity is identified.

Multiple lymph nodes are identified ranging in size from 0.3 x 0.2 x 0.2 cm up to 2.4 x 2.3 x 1.7 cm. Several lymph nodes are grossly positive and deeply pigmented. Representative portions of positive lymph nodes are submitted for tumor bank.

INK CODE: Orange – skin edges

SECTION CODE: A1, two sections of skin with scar; A2-A9, four lymph nodes each; A10, five possible lymph nodes; A11, representative section of largest lymph node; A12, three lymph nodes; A13, two lymph nodes; A14, one lymph node bisected.

CLINICAL HISTORY

Metastatic melanoma

SNOMED CODES

T-C4710, M-87206

1CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axilla C77.3
lw 10/3/11

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file e0fed575-9d5c-4211-8b3f-79d0609581e0 (TCGA-D3-A3C1.C22DE920-6E63-40EE-B58B-D33C37817C49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).